CCDI case PBCPWU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8f6ed842-76bc-4f27-a56a-788af1ed7f5d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.8 years (1,037 days).

Biospecimens (3 samples)
- Sample 0DX0Q7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX0QG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX0R2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
